Somatic mutation profile of tumor specimen TCGA-DD-A4NF-01A (aliquot TCGA-DD-A4NF-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.1 years (26,330 days).
Specimen TCGA-DD-A4NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9788630b-216a-4bcf-b531-53fcd80ad35b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NF-10A (Blood Derived Normal), aliquot TCGA-DD-A4NF-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f50cb7ee-1c92-481a-9a6c-c5c9448f45d2

The open-access MAF lists 128 somatic variants for this specimen: 99 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 27, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 101/277 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- ABCA2 | c.640C>T p.R214C (on ENST00000614293; = p.R184C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.54); catalogued as rs367828133, COSV55802010; called by muse, mutect2
- ABCG2 | c.734C>G p.P245R | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766790636, COSV52946396; called by muse, mutect2, varscan2
- ADAMTSL5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.336); catalogued as rs1034922927, COSV57860648; called by muse, mutect2, varscan2
- ARHGAP44 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52394672; called by muse, mutect2, varscan2
- ARID3C | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV52407516; called by muse, mutect2
- ASCC3 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV61228701; called by muse, mutect2, varscan2
- BACE2 | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV57739906; called by muse, mutect2, varscan2
- BAHCC1 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV57027213; called by muse, mutect2, varscan2
- BDP1 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62431658; called by muse, mutect2
- BICRAL | c.2753C>A p.S918Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.444); catalogued as COSV58405849; called by muse, mutect2, varscan2
- BLM | c.3473A>G p.D1158G | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV61924341; called by muse, mutect2, varscan2
- C11orf1 | c.53A>T p.N18I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV52788556; called by muse, mutect2, varscan2
- C9orf72 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.547); catalogued as COSV66154762; called by muse, mutect2, varscan2
- CASQ1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63624190, COSV63624249; called by muse, mutect2, varscan2
- CD46 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59733455; called by muse, mutect2, varscan2
- CHAT | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60325612; called by muse, mutect2, varscan2
- CIRBP | c.123G>C p.R41S | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58011191; called by muse, mutect2, varscan2
- CRB1 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV66341727; called by muse, varscan2
- CSNK1G1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57310025; called by muse, mutect2, varscan2
- DCAF5 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV58460549; called by muse, mutect2, varscan2
- DENND5B | c.2019G>T p.W673C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.775); catalogued as COSV60902843; called by muse, mutect2, varscan2
- DNAH1 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV70229370; called by muse, mutect2
- DNAH2 | c.11278G>T p.D3760Y | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66720050; called by muse, mutect2, varscan2
- DNAI2 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162719665, COSV56759012; ClinVar: uncertain significance; called by muse, mutect2
- DOCK4 | c.310T>A p.Y104N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV70321003; called by muse, mutect2, varscan2
- DUSP1 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV53320242; called by muse, mutect2, varscan2
- FAT2 | c.9679G>T p.V3227L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as COSV55820464; called by muse, varscan2
- GPR148 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV59308380; called by muse, mutect2, varscan2
- GRXCR1 | c.499C>A p.R167S | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV67671929, COSV67674907; called by muse, mutect2, varscan2
- HDAC4 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.1); catalogued as COSV61866134; called by muse, mutect2, varscan2
- HEATR5B | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV51853208; called by muse, mutect2, varscan2
- HERC2 | c.3439A>G p.K1147E | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55325297; called by muse, mutect2, varscan2
- HTRA4 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV56759537; called by muse, mutect2, varscan2
- HYDIN | c.11643C>G p.H3881Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV66639238; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1818C>A p.F606L | Missense Mutation (SNP) | VAF 212/246 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV61141988, COSV61158755, COSV61159395; called by muse, mutect2, varscan2
- INSL6 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV67563013; called by muse, mutect2, varscan2
- INTS8 | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57376193; called by muse, mutect2, varscan2
- ITSN1 | c.1952G>T p.R651I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV66083384; called by muse, mutect2, varscan2
- KCNB2 | c.87del p.S30Afs*53 | Frame Shift Del (DEL) | VAF 77/169 reads (46%) | catalogued as COSV73048818; called by mutect2, pindel, varscan2
- KDM7A | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV50091699, COSV50092290; called by muse, mutect2, varscan2
- KLHL6 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58066657; called by muse, varscan2
- L1CAM | c.3168A>G p.E1056= | Splice Region (SNP) | VAF 42/85 reads (49%) | catalogued as COSV62828217; called by muse, mutect2, varscan2
- LBR | c.1438A>T p.N480Y | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.396); catalogued as rs1376867105, COSV55289118; called by muse, mutect2, varscan2
- LEF1 | c.281-1G>A p.X94_splice | Splice Site (SNP) | VAF 22/81 reads (27%) | catalogued as COSV54467732; called by muse, mutect2, varscan2
- LNPEP | c.1958A>G p.H653R | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV51478263; called by muse, mutect2, varscan2
- LYAR | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs1402421445, COSV58642941; called by muse, mutect2, varscan2
- MCM4 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs755044869, COSV50624000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRAP2 | c.327C>G p.N109K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV57632584, COSV57632722; called by muse, mutect2, varscan2
- MUC16 | c.5885T>A p.M1962K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV67468925; called by muse, mutect2, varscan2
- MYO6 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64119177; called by muse, mutect2, varscan2
- MYO9A | c.4862C>G p.S1621C | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); catalogued as COSV61851605; called by muse, mutect2, varscan2
- NPAP1 | c.2327C>A p.A776D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV61507469; called by muse, mutect2, varscan2
- OR2T6 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV63216406; called by muse, varscan2
- OR6N2 | c.773T>A p.M258K | Missense Mutation (SNP) | VAF 119/466 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV59411594; called by muse, mutect2, varscan2
- PARP11 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57395137; called by muse, mutect2, varscan2
- PCDH17 | c.2806G>T p.E936* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV64974532; called by muse, mutect2, varscan2
- PCDHA5 | c.561A>C p.E187D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV65352753; called by muse, mutect2, varscan2
- PCDHB13 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 71/189 reads (38%) | catalogued as COSV53394606, COSV99507576; called by muse, mutect2, varscan2
- PHEX | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.232); catalogued as rs757539874, COSV65075837; called by muse, mutect2, varscan2
- PKD1L1 | c.2638C>T p.R880W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs749061984, COSV56966191; called by muse, mutect2, varscan2
- PKP1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55821490; called by muse, mutect2, varscan2
- PLCG2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748440029, COSV63869856; called by muse, mutect2, varscan2
- PLEKHH2 | c.3679G>A p.G1227R | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs755276084, COSV56754697; called by muse, mutect2, varscan2
- POM121L12 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68693045, COSV68694286; called by muse, mutect2
- POR | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58694017; called by muse, mutect2, varscan2
- PREX2 | c.3557A>G p.D1186G | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV55772693; called by muse, mutect2, varscan2
- PRKDC | c.10975T>G p.F3659V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58053211; called by muse, mutect2, varscan2
- PSME3IP1 | c.534T>A p.D178E | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs372644692, COSV58429281; called by muse, mutect2, varscan2
- ROBO1 | c.2955C>A p.N985K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as COSV71394683; called by muse, mutect2, varscan2
- RPE65 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV52016314; called by muse, mutect2, varscan2
- SDHAF2 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV57099333; called by muse, mutect2, varscan2
- SEMA3A | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54871923; called by muse, mutect2, varscan2
- SHROOM4 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 67/86 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV56789790, COSV99057881; called by muse, mutect2, varscan2
- SI | c.4396C>A p.P1466T | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs796683088, COSV100016502; called by muse, mutect2
- SLC7A13 | c.1076T>A p.L359* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV52534689; called by muse, mutect2, varscan2
- SLCO5A1 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765107213, COSV52654489, COSV52663507; called by muse, mutect2, varscan2
- SLIT2 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56574047; called by muse, mutect2, varscan2
- SNCA | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61133837; called by muse, mutect2, varscan2
- SPAG6 | c.505G>T p.V169F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1460514013, COSV57620772; called by muse, mutect2, varscan2
- SPHKAP | c.4259C>A p.S1420* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV60879862, COSV60880669; called by muse, mutect2, varscan2
- SPTA1 | c.5561C>T p.T1854I | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV63753873; called by muse, mutect2, varscan2
- SPTB | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.179); catalogued as COSV67632145; called by muse, mutect2, varscan2
- TAOK2 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1462713646, COSV54236233, COSV99665270; called by muse, mutect2, varscan2
- TBL3 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs755944498, COSV60341531; called by muse, mutect2, varscan2
- TEKT3 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV58627776; called by muse, mutect2, varscan2
- TELO2 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV51978317; called by muse, mutect2, varscan2
- TMEM71 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.599); catalogued as COSV63457614; called by muse, mutect2, varscan2
- USPL1 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV55000121; called by muse, mutect2, varscan2
- VPS50 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as COSV58507808; called by muse, varscan2
- WWC2 | c.1297A>G p.S433G | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66713992; called by muse, mutect2, varscan2
- ZNF37A | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61073797; called by muse, mutect2, varscan2
- ZNF423 | c.1549A>C p.N517H (on ENST00000563137 / NM_001379286.1; = p.N509H on NM_015069.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV52189983; called by muse, mutect2, varscan2
- ZNF440 | c.568C>G p.H190D | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58371221; called by muse, varscan2
- ZNF676 | c.1641C>G p.S547R (on ENST00000650058; = p.S515R on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.765); catalogued as COSV68093244; called by muse, mutect2, varscan2
- FAM111B | c.785_786del p.K262Sfs*19 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel
- IGKV1D-17 | c.5A>T p.D2V | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- INPP5D | c.1253del p.P418Lfs*31 (on ENST00000445964 / NM_001017915.3; = p.P417Lfs*31 on NM_005541.5) | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | called by pindel, varscan2
- ZNF687 | c.2616dup p.M873Hfs*32 | Frame Shift Ins (INS) | VAF 110/270 reads (41%) | called by mutect2, varscan2
- AHCYL1 | c.987T>A p.A329= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV63208728; called by muse, mutect2, varscan2
- C6orf62 | c.405T>C p.S135= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV65290515; called by muse, mutect2, varscan2
- CCDC63 | c.1503C>T p.P501= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV100370314, COSV57528712; called by muse, mutect2
- CDK5R1 | c.150G>A p.L50= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as COSV55578977; called by muse, mutect2, varscan2
- CRISP3 | c.630T>C p.N210= (on ENST00000371159 / NM_001368123.1; = p.N192= on NM_006061.4) | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as COSV53820563; called by muse, mutect2, varscan2
- DHX34 | c.1249C>T p.L417= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV60895608; called by muse, mutect2, varscan2
- FAM76B | c.30C>A p.T10= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV57688740; called by muse, mutect2, varscan2
- GAL | c.315C>G p.L105= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV55764007; called by muse, mutect2, varscan2
- GLYATL2 | c.42T>C p.Y14= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV54850021; called by muse, mutect2, varscan2
- JPH2 | c.1125C>G p.R375= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65903554, COSV65904542; called by muse, mutect2, varscan2
- KIF18A | c.417C>T p.H139= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV54183467, COSV99588283; called by muse, varscan2
- LTBP4 | c.4632C>T p.T1544= (on ENST00000308370 / NM_001042544.1; = p.T1507= on NM_003573.2) | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1405607738, COSV52582144; called by muse, mutect2, varscan2
- MAST1 | c.1263G>A p.V421= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as COSV52247550; called by muse, mutect2, varscan2
- NXPH4 | c.393T>C p.H131= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs938734255, COSV61074084; called by muse, mutect2, varscan2
- OBSCN | c.4755G>T p.V1585= | Silent (SNP) | VAF 79/149 reads (53%) | catalogued as COSV52746549; called by muse, mutect2, varscan2
- OBSCN | c.7251G>T p.T2417= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV52778616; called by muse, mutect2, varscan2
- OR2T34 | c.672C>G p.T224= | Silent (SNP) | VAF 145/628 reads (23%) | catalogued as rs760863276, COSV60900596; called by muse, mutect2, varscan2
- OR51L1 | c.897G>A p.K299= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV58624847; called by muse, mutect2, varscan2
- PDIA4 | c.1224G>A p.K408= (on ENST00000286091 / NM_001371244.1; = p.K407= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV53724934; called by muse, mutect2, varscan2
- PHF8 | c.1425G>A p.L475= (on ENST00000357988 / NM_001184896.1; = p.L439= on NM_015107.3) | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV57681977; called by muse, mutect2, varscan2
- PKHD1L1 | c.297A>G p.T99= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV65743776; called by muse, mutect2, varscan2
- RBFOX1 | c.193C>T p.L65= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV60960277; called by muse, mutect2, varscan2
- RXRG | c.522G>T p.T174= | Silent (SNP) | VAF 85/418 reads (20%) | catalogued as COSV63232205; called by muse, mutect2, varscan2
- SACS | c.10219C>T p.L3407= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV66540461, COSV66543423; called by muse, mutect2, varscan2
- SLC9B1 | c.51A>G p.Q17= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56470502; called by muse, mutect2, varscan2
- SMC5 | c.261G>T p.S87= | Silent (SNP) | VAF 60/153 reads (39%) | catalogued as COSV63193069; called by muse, mutect2, varscan2
- SPATA13 | c.993T>C p.Y331= | Silent (SNP) | VAF 71/174 reads (41%) | catalogued as COSV57977957; called by muse, mutect2, varscan2
- DEPDC5 | c.*1038A>G | 3'UTR (SNP) | VAF 8/159 reads (5%) | catalogued as COSV99836016; called by muse, mutect2
- ETFB | c.58-44G>A | Intron (SNP) | VAF 18/41 reads (44%) | catalogued as rs776379865, COSV58536087; called by muse, mutect2, varscan2
